Somatic mutation profile of tumor specimen MMRF_1671_1_BM_CD138pos (aliquot MMRF_1671_1_BM_CD138pos_T1_KBS5U_L04815) from MMRF case MMRF_1671, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,073 days).
Specimen MMRF_1671_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b0b0e40-da6c-424b-b5c7-19a203e0922f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1671_4_PB_WBC (Blood Derived Normal), aliquot MMRF_1671_4_PB_WBC_C3_KHS5U_L15743; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331b7e47-9e91-4773-89b3-26693329e93d

The open-access MAF lists 88 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 15, Silent 11, Intron 11, Splice Site 5, Nonsense Mutation 5, 3'Flank 3, 5'UTR 2, Frame Shift Del 2, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 159/332 reads (48%) | catalogued as rs769676029, COSV59592240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ELANE | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as rs1555710005, CS091635, CS112156, CS993231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs794728325, CM091205, CM091206, CS013965, COSV57313335; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 50/100 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1216946686, COSV101144153; called by muse, mutect2
- ATP13A5 | c.2899C>A p.Q967K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.103); catalogued as rs753858029; called by muse, mutect2, varscan2
- CSMD1 | c.3614G>T p.G1205V (on ENST00000520002; = p.G1204V on NM_033225.6) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59381907; called by muse, mutect2, varscan2
- CSPG5 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751401533; called by muse, mutect2, varscan2
- DCHS1 | c.4252C>T p.R1418W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs749199604; called by muse, mutect2, varscan2
- DDX60 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778995813; called by muse, mutect2, varscan2
- EIF3E | c.661_664del p.V221Sfs*36 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs762916048; called by pindel, varscan2
- EPHA4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs1346215997; called by muse, mutect2, varscan2
- FAT3 | c.4139T>G p.I1380S | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV53070857; called by muse, mutect2, varscan2
- GPR142 | c.1254C>G p.S418R | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs368187784; called by muse, mutect2, varscan2
- HIVEP3 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs540145704, COSV56014541; called by muse, mutect2, varscan2
- HMX1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1336325306; called by muse, mutect2, varscan2
- IGLV3-1 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs61731694; called by muse, varscan2
- KRT3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546099163, COSV58815743; called by muse, varscan2
- NCAPH2 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 101/177 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752146981, COSV52687158; called by muse, mutect2, varscan2
- NCOA1 | c.4155+1G>T p.X1385_splice | Splice Site (SNP) | VAF 46/110 reads (42%) | catalogued as rs769235879; called by muse, mutect2, varscan2
- SPATA31E1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1184361142; called by muse, mutect2, varscan2
- TEP1 | c.3867+2T>G p.X1289_splice | Splice Site (SNP) | VAF 66/141 reads (47%) | catalogued as COSV52993602; called by muse, mutect2, varscan2
- UBR5 | c.8176C>T p.R2726* | Nonsense Mutation (SNP) | VAF 4/81 reads (5%) | catalogued as COSV55280901; called by muse, mutect2
- AHNAK | c.10207T>A p.F3403I | Missense Mutation (SNP) | VAF 152/306 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDK13 | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CFAP47 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DKK2 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- ENOSF1 | c.846C>A p.C282* (on ENST00000340116 / NM_001354066.2; = p.C234* on NM_017512.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/335 reads (3%) | called by muse, mutect2
- FAM83E | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBXO30 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXA1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- HELZ2 | c.1964_1990del p.R655_H663del (on ENST00000467148 / NM_001037335.2; = p.R86_H94del on NM_033405.3) | In Frame Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- HUWE1 | c.2261+1G>A p.X754_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, varscan2
- IGSF21 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KDM3B | c.5187T>G p.N1729K | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LKAAEAR1 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- NUFIP2 | c.843_849del p.Y282Lfs*27 | Frame Shift Del (DEL) | VAF 87/216 reads (40%) | called by mutect2, pindel, varscan2
- PKHD1 | c.6635C>A p.A2212D | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- QRFPR | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RAP1GAP | c.1000-1G>A p.X334_splice | Splice Site (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- RHEBL1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STK32A | c.856T>G p.W286G | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIM9 | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP45 | c.492C>T p.I164= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- CD19 | c.1632C>A p.A544= (on ENST00000324662 / NM_001178098.2; = p.A543= on NM_001770.6) | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CPA4 | c.1014G>A p.A338= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs577880214; called by muse, mutect2, varscan2
- CRACDL | c.607C>T p.L203= | Silent (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- EVC | c.1074C>T p.C358= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as rs921573510, COSV53832080; called by muse, mutect2, varscan2
- KCNB2 | c.447C>T p.N149= | Silent (SNP) | VAF 139/300 reads (46%) | catalogued as rs755305477, COSV101578734, COSV73048698; called by muse, mutect2, varscan2
- NTRK2 | c.2103G>T p.V701= (on ENST00000323115 / NM_001369534.1; = p.V717= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- PEMT | c.282C>T p.L94= | Silent (SNP) | VAF 68/143 reads (48%) | catalogued as rs753328073; called by muse, mutect2, varscan2
- SYNC | c.186G>A p.E62= | Silent (SNP) | VAF 124/285 reads (44%) | catalogued as COSV65131234; called by muse, mutect2, varscan2
- TTN | c.99648G>A p.L33216= (on ENST00000591111; = p.L25792= on NM_003319.4) | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- ZNF510 | c.54C>T p.G18= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV56296644; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2212C>G | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- AKAP1 | c.1714+809A>G | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- AL132796.2 | n.648C>G | RNA (SNP) | VAF 76/156 reads (49%) | called by muse, mutect2, varscan2
- BNIPL | c.*341C>T | 3'UTR (SNP) | VAF 21/81 reads (26%) | catalogued as rs748564594; called by muse, mutect2, varscan2
- CCDC68 | chr18:54903648 G>T | 3'Flank (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018802 G>T | 3'Flank (SNP) | VAF 68/131 reads (52%) | called by muse, mutect2, varscan2
- CLPTM1 | c.72+148C>T | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- DPP10 | c.*3098A>T | 3'UTR (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- DSC2 | c.*174C>A | 3'UTR (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- GET4 | c.235-54C>T | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- KIAA1109 | c.*408A>T | 3'UTR (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- LBR | c.166-9C>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- LRIT2 | c.*809A>C | 3'UTR (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- NEUROD6 | c.*294G>A | 3'UTR (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*3919T>C | 3'UTR (SNP) | VAF 342/547 reads (63%) | called by muse, mutect2, varscan2
- PAN2 | c.*631G>A | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- PCDH15 | c.*229G>A | 3'UTR (SNP) | VAF 69/154 reads (45%) | catalogued as rs974421099; called by muse, mutect2, varscan2
- PCK1 | c.406+139T>A | Intron (SNP) | VAF 24/43 reads (56%) | called by muse, varscan2
- PDE1C | c.1892-8227T>C | Intron (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- POR | c.-5+11T>A | Intron (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- POU2F2 | chr19:42089640 C>T | 3'Flank (SNP) | VAF 74/141 reads (52%) | called by muse, mutect2, varscan2
- PTPN13 | c.4149+15G>A | Intron (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- PTPRN2 | c.*1536T>A | 3'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- RFT1 | c.-8C>T | 5'UTR (SNP) | VAF 30/72 reads (42%) | catalogued as rs766568297; called by muse, mutect2, varscan2
- RPL31 | c.*106C>T | 3'UTR (SNP) | VAF 279/563 reads (50%) | called by muse, mutect2, varscan2
- SHF | c.303+154C>G | Intron (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- TAFA5 | c.*1701G>A | 3'UTR (SNP) | VAF 59/124 reads (48%) | catalogued as rs1241119143; called by muse, mutect2, varscan2
- TMEM185A | c.*847T>C | 3'UTR (SNP) | VAF 61/104 reads (59%) | called by muse, mutect2, varscan2
- TMSB4X | c.-78T>C | 5'UTR (SNP) | VAF 76/77 reads (99%) | called by muse, mutect2, varscan2
- TRERF1 | c.*2994C>A | 3'UTR (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- UNC5C | c.775+2033A>C | Intron (SNP) | VAF 63/119 reads (53%) | called by muse, mutect2, varscan2
- VCP | chr9:35072721 T>C | 5'Flank (SNP) | VAF 79/155 reads (51%) | catalogued as rs527975908; called by muse, mutect2, varscan2
- ZFC3H1 | c.*239C>T | 3'UTR (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
